Somatic mutation profile of tumor specimen TARGET-10-PATMAF-09A (aliquot TARGET-10-PATMAF-09A-01D) from TARGET case TARGET-10-PATMAF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.5 years (6,011 days).
Specimen TARGET-10-PATMAF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b1c3d07-17cb-4e01-9068-6ee3cd8bae1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATMAF-10A (Blood Derived Normal), aliquot TARGET-10-PATMAF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea61db58-9021-40fe-8ab8-34bf5dd95837

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Nonsense Mutation 4, Splice Site 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL4 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs1172330874, COSV55000338; called by muse, mutect2, varscan2
- ANK3 | c.10838G>T p.R3613L | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV55050330, COSV55057604; called by muse, mutect2
- CALHM1 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375270464; called by muse, mutect2, varscan2
- CARD10 | c.2175C>G p.C725W | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV52658120, COSV52659789; called by muse, mutect2, varscan2
- ERBB4 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.063); catalogued as rs762812065, COSV53507423, COSV53550901; called by muse, varscan2
- IKZF2 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 54/87 reads (62%) | catalogued as COSV59580602; called by muse, mutect2, varscan2
- KIAA1614 | c.1807G>A p.V603M | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as rs777658675, COSV62551236; called by mutect2, varscan2
- KMT2E | c.3298C>T p.R1100* | Nonsense Mutation (SNP) | VAF 11/110 reads (10%) | catalogued as COSV57576130, COSV57580158; called by muse, mutect2
- NFE2L3 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs770073786, COSV50231327; called by mutect2, varscan2
- NOTCH1 | c.4802A>C p.H1601P | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV53066978, COSV99489272; called by muse, mutect2, varscan2
- PCDHAC1 | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141879545; called by muse, varscan2
- PTPRC | c.3646-2A>G p.X1216_splice | Splice Site (SNP) | VAF 55/168 reads (33%) | catalogued as COSV61415253; called by muse, mutect2, varscan2
- SLC5A2 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as rs1249440849, COSV57892814; called by muse, mutect2, varscan2
- SUZ12 | c.1952A>T p.N651I | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59501412; called by muse, varscan2
- TRAF3IP2 | c.1435G>A p.V479M | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237812708, COSV60676156; called by muse, mutect2, varscan2
- UTY | c.3173_3174insGAT p.R1058_V1059insI | In Frame Ins (INS) | VAF 34/38 reads (89%) | catalogued as COSV58870644; called by mutect2, varscan2
- VPS13D | c.12620C>A p.T4207K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs940548529; called by muse, mutect2
- FAM160A1 | c.876C>A p.C292* | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- GAREM1 | c.1067G>T p.S356I | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- PTPRC | c.2258_2259insGGCTTG p.R753_C754insA* | Nonsense Mutation (INS) | VAF 70/310 reads (23%) | called by mutect2, varscan2
- FNDC3B | c.24C>T p.T8= | Silent (SNP) | VAF 84/178 reads (47%) | catalogued as rs539042799, COSV100394909; called by muse, varscan2
- GLIS3 | c.1341G>A p.P447= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as rs377400577; called by muse, mutect2, varscan2
- KIAA0100 | c.2772G>A p.E924= | Silent (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- NCOA1 | c.3867G>A p.A1289= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs1000357865; called by muse, mutect2, varscan2
- NDST2 | c.2319G>T p.L773= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100014062; called by muse, mutect2
- SP8 | c.369C>T p.N123= (on ENST00000361443 / NM_198956.4; = p.N141= on NM_182700.6) | Silent (SNP) | VAF 14/20 reads (70%) | called by mutect2, varscan2
- LIMK1 | c.153-3342C>A | Intron (SNP) | VAF 42/102 reads (41%) | catalogued as rs1163322513, COSV100283375; called by muse, varscan2
